Somatic mutation profile of tumor specimen C3N-02700-01 (aliquot CPT0177010006) from CPTAC case C3N-02700, project CPTAC-3 (Lip — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lip, NOS; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 80.8 years (29,529 days).
Specimen C3N-02700-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lip; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2f41881-1176-43d1-bdff-6f0440ca3726.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02700-71 (Blood Derived Normal), aliquot CPT0177130002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6322038-85fd-4826-ba5a-f60d2e936608

The open-access MAF lists 1,783 somatic variants for this specimen: 1,078 protein-altering or splice-affecting, 505 silent, 200 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 975, Silent 505, Intron 85, Nonsense Mutation 52, 3'UTR 31, RNA 31, Splice Region 26, 5'UTR 23, 5'Flank 22, Splice Site 18, 3'Flank 8, Translation Start Site 3.

Variants (750 of 1,783; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.330G>A p.W110* | Nonsense Mutation (SNP) | VAF 360/759 reads (47%) | hotspot (GDC flag); catalogued as rs121913389, CM060208, COSV58682827, COSV58708986; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IGHMBP2 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 53/190 reads (28%) | catalogued as rs773690764, CM035785; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 42/235 reads (18%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- TP53 | c.672+1G>A p.X224_splice | Splice Site (SNP) | VAF 42/248 reads (17%) | hotspot (GDC flag); catalogued as rs863224499, CS071266, CS123101, COSV52670407, COSV52712339, COSV52751788; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.672G>A p.E224= | Splice Region (SNP) | VAF 42/246 reads (17%) | catalogued as rs267605076, CS100446, COSV52678333, COSV52681634, COSV52721244; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB4 | c.3247G>A p.E1083K | Missense Mutation (SNP) | VAF 44/226 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs761598845, COSV55933699; ClinVar: uncertain significance; called by muse, varscan2
- ABCC9 | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs1025600293, COSV53967191; called by muse, mutect2, varscan2
- ABCD1 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as CD961755, CM106587, CM984040; called by muse, mutect2, varscan2
- ACAA2 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs762009554; called by muse, mutect2, varscan2
- ACIN1 | c.2474C>T p.S825F | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52975631; called by muse, mutect2, varscan2
- ACKR1 | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as rs749827595; called by muse, mutect2
- ACSL6 | c.1975C>T p.H659Y (on ENST00000379240; = p.H684Y on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); catalogued as COSV57298527; called by muse, mutect2, varscan2
- ACSM2A | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 55/245 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV54585410; called by muse, mutect2, varscan2
- ACTN2 | c.2377G>A p.E793K | Missense Mutation (SNP) | VAF 143/549 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs145450474, COSV63977118; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM20 | c.2000G>A p.G667D | Missense Mutation (SNP) | VAF 113/233 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761473055; called by muse, mutect2, varscan2
- ADAMTS12 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 149/306 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as rs144557630, COSV100711718; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2873G>A p.R958Q | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as rs192319648, COSV54439281, COSV54462993; called by muse, mutect2, varscan2
- ADGB | c.4471G>A p.E1491K | Missense Mutation (SNP) | VAF 70/310 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as rs773935657, COSV58850983; called by muse, mutect2, varscan2
- ADGRA1 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs753948568; called by muse, mutect2, varscan2
- ADGRA1 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.175); catalogued as COSV104433478, COSV66927386; called by muse, mutect2, varscan2
- ADGRF3 | c.320G>A p.G107E (on ENST00000311519 / NM_001145168.1; = p.G48E on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV61050006; called by muse, mutect2, varscan2
- ADGRL3 | c.2992G>A p.G998R (on ENST00000506720 / NM_001322402.2; = p.G930R on NM_015236.6) | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72230418; called by muse, mutect2, varscan2
- ADGRL4 | c.1432C>T p.L478F | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1420403802, COSV66061051; called by muse, mutect2, varscan2
- ADNP | c.3095C>T p.S1032F | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV62425738; called by muse, mutect2, varscan2
- AK7 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV50878710; called by muse, mutect2, varscan2
- AKR1E2 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 49/234 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53631267; called by muse, mutect2, varscan2
- ALAS2 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs201086991, COSV100238716; called by muse, mutect2, varscan2
- ALDOB | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 77/329 reads (23%) | SIFT tolerated (0.85); PolyPhen benign (0.015); catalogued as rs867022678, COSV66397306; called by muse, mutect2, varscan2
- ALK | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 78/349 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.809); catalogued as rs200364883, COSV66561092, COSV66594696; called by muse, mutect2, varscan2
- ALX3 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 95/365 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs865785395; called by muse, mutect2, varscan2
- AMY2A | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.721); catalogued as rs772054028; called by muse, mutect2, varscan2
- ANGPTL6 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1383217858; called by muse, mutect2, varscan2
- ANKIB1 | c.2965C>T p.P989S | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV56065143; called by muse, mutect2, varscan2
- ANKRD30B | c.634G>T p.A212S | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.931); catalogued as COSV62815462; called by muse, mutect2, varscan2
- ANKRD30B | c.3803G>A p.R1268Q | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs779937678, COSV100271436, COSV57703864; called by muse, mutect2, varscan2
- ANKRD36B | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.134); catalogued as rs748321795; called by muse, mutect2, varscan2
- APOB | c.10375G>A p.E3459K | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.996); catalogued as COSV99267567; called by muse, mutect2, varscan2
- ARAF | c.1246G>A p.G416S | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51691704; called by muse, mutect2, varscan2
- ARHGAP24 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs1382835691; called by muse, mutect2, varscan2
- ARHGAP25 | c.808-5C>T | Splice Region (SNP) | VAF 69/242 reads (29%) | catalogued as COSV99771883; called by muse, mutect2, varscan2
- ARHGAP6 | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 28/125 reads (22%) | catalogued as rs1398086454; called by muse, mutect2, varscan2
- ARL10 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 137/493 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV100055361, COSV53798818; called by muse, mutect2, varscan2
- ASTN1 | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs1386515526, COSV56088677; called by muse, mutect2, varscan2
- ASXL3 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.992); catalogued as rs931090804; called by muse, mutect2, varscan2
- ATF4 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1180976813, COSV57479973; called by muse, mutect2, varscan2
- ATP1A2 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 93/387 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as rs752936420, COSV100768232, COSV63405458; called by muse, mutect2, varscan2
- BBX | c.936G>A p.M312I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100362368, COSV57892870; called by muse, mutect2, varscan2
- BCL9 | c.1819C>T p.P607S | Missense Mutation (SNP) | VAF 66/302 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.081); catalogued as rs781996874; called by muse, mutect2, varscan2
- BCORL1 | c.3344C>T p.P1115L | Missense Mutation (SNP) | VAF 62/261 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as rs774565678; called by muse, mutect2, varscan2
- BPIFA2 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99487901; called by muse, mutect2, varscan2
- BRAF | c.2165G>A p.R722Q (on ENST00000288602 / NM_001374244.1; = p.R682Q on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.352); catalogued as COSV56096882; called by muse, mutect2, varscan2
- BRINP2 | c.542G>A p.G181E | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.067); catalogued as COSV100838529, COSV64175535; called by muse, mutect2, varscan2
- BTNL8 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV51458004; called by muse, mutect2, varscan2
- C10orf90 | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 47/275 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774149776, COSV52951772; called by muse, mutect2, varscan2
- C1QL2 | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 73/277 reads (26%) | catalogued as rs879501674, COSV55607575; called by muse, mutect2, varscan2
- C2CD4B | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 75/271 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.424); catalogued as rs927273342; called by muse, mutect2, varscan2
- C4orf54 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs745635733, COSV101552164; called by muse, mutect2, varscan2
- C9orf131 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV100398185; called by muse, mutect2, varscan2
- CABIN1 | c.3193C>T p.H1065Y | Missense Mutation (SNP) | VAF 49/280 reads (18%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.994); catalogued as COSV54082720; called by muse, mutect2, varscan2
- CACNA2D2 | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 65/227 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56562084; called by muse, mutect2, varscan2
- CAD | c.3618G>A p.K1206= | Splice Region (SNP) | VAF 69/227 reads (30%) | catalogued as COSV53031360; called by muse, mutect2, varscan2
- CADPS | c.2458-1G>A p.X820_splice | Splice Site (SNP) | VAF 25/87 reads (29%) | catalogued as COSV99341954; called by muse, varscan2
- CAPN11 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755910697; called by muse, mutect2, varscan2
- CAPNS2 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs1484951014; called by muse, mutect2, varscan2
- CBY2 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.994); catalogued as COSV60117578; called by muse, mutect2, varscan2
- CCDC168 | c.4654C>T p.L1552F | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.08); catalogued as COSV70554880; called by muse, mutect2, varscan2
- CCDC168 | c.2197G>A p.E733K | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as rs1001492843; called by muse, mutect2, varscan2
- CCN4 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 109/331 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1335254241; called by muse, mutect2, varscan2
- CD163L1 | c.1514G>A p.W505* | Nonsense Mutation (SNP) | VAF 24/84 reads (29%) | catalogued as COSV58022887; called by muse, mutect2, varscan2
- CDC27 | c.2344C>T p.R782C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV50364249; called by muse, mutect2, varscan2
- CDH10 | c.1875G>A p.L625= | Splice Region (SNP) | VAF 19/162 reads (12%) | catalogued as rs184571175, COSV52572288; called by muse, mutect2, varscan2
- CDH10 | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 36/291 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV52582639; called by muse, mutect2, varscan2
- CDHR5 | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 71/274 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs111358941; called by muse, mutect2, varscan2
- CEP131 | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 65/278 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as rs752493334; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.387); catalogued as rs748823469, COSV55828740; called by muse, mutect2, varscan2
- CFAP47 | c.7601A>C p.N2534T | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV66216677; called by muse, mutect2, varscan2
- CFAP74 | c.1423C>T p.R475* | Nonsense Mutation (SNP) | VAF 41/106 reads (39%) | catalogued as rs889184555; called by muse, mutect2, varscan2
- CFHR2 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.019); catalogued as rs370528458, COSV66381914; called by muse, mutect2, varscan2
- CFHR5 | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as rs1428247213; called by muse, mutect2, varscan2
- CFTR | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 63/219 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM076095; called by muse, mutect2, varscan2
- CHD4 | c.3479G>A p.R1160Q (on ENST00000357008 / NM_001363606.2; = p.R1173Q on NM_001273.5) | Missense Mutation (SNP) | VAF 79/330 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV99046261; called by muse, mutect2, varscan2
- CHD5 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as rs1231112944, COSV52426423; called by muse, mutect2, varscan2
- CHFR | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 70/352 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs746187833; called by muse, varscan2
- CHM | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63300475; called by muse, mutect2, varscan2
- CHRDL1 | c.391C>T p.R131W (on ENST00000372045; = p.R137W on NM_145234.4) | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749956744, COSV54324410; called by muse, mutect2, varscan2
- CIITA | c.1327C>T p.P443S | Missense Mutation (SNP) | VAF 59/180 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.224); catalogued as rs1465699067; called by muse, mutect2, varscan2
- COL19A1 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.659); catalogued as rs771341446; called by muse, mutect2, varscan2
- COL22A1 | c.4705G>A p.E1569K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.192); catalogued as rs781121978, COSV57332861; called by muse, mutect2, varscan2
- COL22A1 | c.2594G>A p.G865E | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs983264212, COSV57344323; called by muse, mutect2, varscan2
- COL28A1 | c.2722G>A p.D908N | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV68083504; called by muse, mutect2, varscan2
- COL4A2 | c.2555C>T p.P852L | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.208); catalogued as rs918015888, COSV64629792; called by muse, mutect2, varscan2
- COL4A2 | c.4157G>A p.G1386E | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267603757, COSV64626787; called by muse, mutect2, varscan2
- COL6A5 | c.6161G>A p.G2054E (on ENST00000312481; = p.G2050E on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752087466, COSV55220225; called by muse, mutect2, varscan2
- COP1 | c.1162C>A p.Q388K | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.678); catalogued as rs1474592774, COSV100443400; called by muse, mutect2
- CPA2 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as rs1439201106, COSV55979195; called by muse, mutect2, varscan2
- CPB2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.46); catalogued as COSV51675612; called by muse, mutect2, varscan2
- CPSF6 | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.968); catalogued as rs867013321; called by muse, mutect2, varscan2
- CRHBP | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs866538801; called by muse, mutect2, varscan2
- CRLF2 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 60/294 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0.062); catalogued as COSV67493457; called by muse, mutect2, varscan2
- CRYBB2 | c.205G>A p.G69S | Missense Mutation (SNP) | VAF 89/458 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV68005520; called by muse, mutect2, varscan2
- CRYBB2 | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 89/456 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101236789; called by muse, mutect2, varscan2
- CSF2RB | c.2209C>T p.P737S | Missense Mutation (SNP) | VAF 110/363 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.503); catalogued as rs760821596; called by muse, mutect2, varscan2
- CSMD1 | c.2429A>T p.Y810F (on ENST00000520002; = p.Y809F on NM_033225.6) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.81); catalogued as rs1260114641; called by muse, varscan2
- CSMD1 | c.1621G>C p.G541R (on ENST00000520002; = p.G540R on NM_033225.6) | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757334022, COSV59313264; called by muse, mutect2, varscan2
- CSMD2 | c.9859G>A p.G3287R | Missense Mutation (SNP) | VAF 45/234 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1353077473, COSV53886168; called by muse, mutect2, varscan2
- CTAGE9 | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 67/438 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.912); catalogued as rs774912126, COSV58418435; called by muse, mutect2, varscan2
- CTNNB1 | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 88/324 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.01); catalogued as COSV100846202; called by muse, mutect2, varscan2
- CTRB1 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 62/251 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750283542; called by muse, mutect2, varscan2
- CX3CL1 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV50055476; called by muse, mutect2, varscan2
- CYLC1 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV104412415; called by muse, mutect2, varscan2
- CYLC1 | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.046); catalogued as rs1470531952; called by muse, mutect2, varscan2
- CYP2C8 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs756095494; called by muse, mutect2, varscan2
- CYP2D7 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs747712020; called by muse, mutect2, varscan2
- CYP3A7 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 65/284 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs768263337, COSV60480465; called by muse, mutect2, varscan2
- DAB2 | c.525G>C p.K175N | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100298456; called by muse, mutect2, varscan2
- DACH1 | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV100499475; called by muse, mutect2, varscan2
- DCHS1 | c.3742G>A p.E1248K | Missense Mutation (SNP) | VAF 51/302 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs780679282; called by muse, mutect2, varscan2
- DGKK | c.1513G>A p.G505R | Missense Mutation (SNP) | VAF 45/229 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65707183; called by muse, mutect2, varscan2
- DISP2 | c.2150G>A p.G717D | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51145829; called by muse, mutect2, varscan2
- DISP2 | c.3457G>A p.G1153R | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV51117836; called by muse, mutect2, varscan2
- DLG3 | c.840+1G>A p.X280_splice | Splice Site (SNP) | VAF 16/58 reads (28%) | catalogued as rs1212006965; called by muse, mutect2, varscan2
- DMD | c.9514C>T p.P3172S | Missense Mutation (SNP) | VAF 90/384 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100626696; called by muse, mutect2, varscan2
- DNAH1 | c.8176C>T p.R2726C | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745633639, COSV70226882; called by muse, mutect2, varscan2
- DNAH3 | c.1016G>A p.W339* | Nonsense Mutation (SNP) | VAF 56/251 reads (22%) | catalogued as rs1567851703; called by muse, mutect2, varscan2
- DNAH3 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 107/296 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs138032546, COSV99770351; called by muse, mutect2, varscan2
- DNAH7 | c.7333G>A p.D2445N | Missense Mutation (SNP) | VAF 69/194 reads (36%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.967); catalogued as COSV56762150; called by muse, mutect2, varscan2
- DNAH8 | c.2085A>T p.Q695H | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV59456004; called by muse, mutect2, varscan2
- DNAI2 | c.348C>T p.I116= | Splice Region (SNP) | VAF 70/356 reads (20%) | catalogued as COSV56759554; called by muse, mutect2, varscan2
- DOCK11 | c.4207G>A p.E1403K | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52236157; called by muse, mutect2, varscan2
- DOP1B | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67695379; called by muse, mutect2, varscan2
- DPAGT1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 84/337 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751590922; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSP | c.8504C>T p.S2835F | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV60939835; called by muse, mutect2, varscan2
- EGR3 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 78/275 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57833881; called by muse, mutect2, varscan2
- ELAVL4 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs755538583, COSV63915662; called by muse, mutect2, varscan2
- ELF3 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as rs777842676, COSV62839639; called by muse, mutect2, varscan2
- EPHA7 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1562049937; called by muse, mutect2, varscan2
- ERC1 | c.2060C>T p.S687F (on ENST00000360905 / NM_178040.4; = p.S659F on NM_178039.4) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV61696905; called by muse, mutect2, varscan2
- ERICH3 | c.1564C>T p.Q522* | Nonsense Mutation (SNP) | VAF 22/116 reads (19%) | catalogued as COSV58615709; called by muse, mutect2, varscan2
- ERN2 | c.1586G>A p.G529E | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56832412; called by muse, mutect2, varscan2
- EVA1B | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 119/435 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1443032471; called by muse, mutect2, varscan2
- F10 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 68/364 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV65020695; called by muse, mutect2, varscan2
- FAM151A | c.801-1G>A p.X267_splice | Splice Site (SNP) | VAF 22/104 reads (21%) | catalogued as rs780265540; called by muse, mutect2, varscan2
- FAM229A | c.282-5C>T | Splice Region (SNP) | VAF 14/38 reads (37%) | catalogued as rs1198407727; called by muse, mutect2, varscan2
- FAM47B | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV61454002; called by muse, mutect2, varscan2
- FAM47B | c.886C>T p.H296Y | Missense Mutation (SNP) | VAF 84/397 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as rs757433063; called by muse, mutect2, varscan2
- FAT3 | c.4264G>A p.D1422N | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99970356; called by muse, mutect2, varscan2
- FAT3 | c.7421G>A p.G2474E | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408229400; called by muse, mutect2, varscan2
- FBN3 | c.7221T>G p.D2407E | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1164766279; called by muse, mutect2, varscan2
- FBXO31 | c.1423G>A p.G475S | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.999); catalogued as rs1456264695; called by muse, mutect2, varscan2
- FBXO38 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as COSV57027685; called by muse, mutect2, varscan2
- FCRL3 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs375378164, COSV100942769, COSV63839727; called by muse, mutect2, varscan2
- FCRL4 | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 52/227 reads (23%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.577); catalogued as COSV54863039; called by muse, mutect2, varscan2
- FGD3 | c.2173C>T p.P725S | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs775796206; called by muse, mutect2, varscan2
- FGF12 | c.295G>A p.E99K (on ENST00000454309 / NM_021032.5; = p.E37K on NM_004113.6) | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as rs865909944, COSV53177161; called by muse, mutect2, varscan2
- FGFR4 | c.2113G>A p.G705R | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52810254; called by muse, mutect2, varscan2
- FHAD1 | c.3425G>A p.R1142Q | Missense Mutation (SNP) | VAF 70/220 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs749109875; called by muse, mutect2, varscan2
- FIGN | c.1681G>A p.G561R | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as rs367860574; called by muse, mutect2, varscan2
- FILIP1 | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs776455963, COSV52725973; called by muse, mutect2, varscan2
- FILIP1 | c.1962G>A p.M654I | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.056); catalogued as COSV52724674; called by muse, mutect2, varscan2
- FLG2 | c.4922G>A p.R1641K | Missense Mutation (SNP) | VAF 77/299 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as rs767154074, COSV66167304; called by muse, mutect2, varscan2
- FMN2 | c.3817G>A p.G1273R | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs750916075, COSV100146160; called by muse, mutect2, varscan2
- FN1 | c.6668G>A p.R2223Q (on ENST00000359671 / NM_001365524.2; = p.R2192Q on NM_002026.4) | Missense Mutation (SNP) | VAF 80/212 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs889502429, COSV60551035; called by muse, mutect2, varscan2
- FOSL2 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 127/530 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs143477470; called by muse, mutect2, varscan2
- FREM1 | c.3601T>C p.F1201L | Missense Mutation (SNP) | VAF 112/242 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV66532064; called by muse, mutect2, varscan2
- FREM1 | c.902C>A p.A301D | Missense Mutation (SNP) | VAF 89/190 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV100772185; called by muse, mutect2, varscan2
- FRMPD3 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 59/301 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1569423695; called by muse, mutect2, varscan2
- FRRS1 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs373614581; called by muse, mutect2, varscan2
- FTMT | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as rs371405042; called by muse, mutect2, varscan2
- FUT9 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs867214750; called by muse, mutect2, varscan2
- GABRG2 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 41/271 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs778814579, COSV62720746; called by muse, mutect2, varscan2
- GCOM1 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 16/117 reads (14%) | catalogued as rs1481221790; called by muse, mutect2, varscan2
- GFAP | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0.366); catalogued as COSV53650893; called by muse, mutect2, varscan2
- GFPT2 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 63/237 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.941); catalogued as rs370443163; called by muse, mutect2, varscan2
- GIMAP1 | c.220G>C p.D74H | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV100212359; called by muse, mutect2, varscan2
- GLIS1 | c.1736C>T p.P579L | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.104); catalogued as rs1379996393, COSV56543029; called by muse, mutect2, varscan2
- GLYATL2 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54849906, COSV99780152; called by muse, mutect2, varscan2
- GLYCTK | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.009); catalogued as COSV59794076; called by muse, mutect2, varscan2
- GOLGA4 | c.3356C>T p.S1119F | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.392); catalogued as COSV100729233; called by muse, mutect2, varscan2
- GOLGA6L22 | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 145/788 reads (18%) | SIFT deleterious (0.04); catalogued as rs766981201; called by muse, varscan2
- GOLIM4 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.091); catalogued as rs146720058; called by muse, mutect2, varscan2
- GPR101 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs761526487, COSV53240593; called by muse, mutect2, varscan2
- GPT | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 70/315 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as rs144054398; called by muse, mutect2, varscan2
- GRIA3 | c.2162G>A p.G721E | Missense Mutation (SNP) | VAF 75/255 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52051185; called by muse, mutect2, varscan2
- GRID2IP | c.2396C>T p.P799L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.808); catalogued as rs1445131927; called by muse, mutect2, varscan2
- GRIK5 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as rs143057585, COSV99490242; called by muse, mutect2, varscan2
- GSPT2 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as COSV61213617; called by muse, mutect2, varscan2
- GTF2B | c.35G>T p.R12I | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV65137644; called by muse, mutect2, varscan2
- GTF3C4 | c.2263C>T p.P755S | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs867559745; called by muse, mutect2, varscan2
- GYPA | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.156); catalogued as COSV51625698; called by muse, mutect2, varscan2
- H1-5 | c.615_629del p.P213_K217del | In Frame Del (DEL) | VAF 36/162 reads (22%) | catalogued as rs758100284; called by mutect2, varscan2
- H1-6 | c.499G>C p.G167R | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV58090187; called by muse, mutect2, varscan2
- HARS1 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs753737068; called by muse, mutect2, varscan2
- HCLS1 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 75/371 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as rs140445778; called by muse, mutect2, varscan2
- HCRTR2 | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs201301558, COSV63793801, COSV63798056, COSV63799846; called by muse, mutect2, varscan2
- HDGFL2 | c.2005G>A p.E669K (on ENST00000616600 / NM_001001520.3; = p.E668K on NM_032631.4) | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious, low confidence (0.01); catalogued as rs546333702; called by muse, mutect2, varscan2
- HEPH | c.2798C>T p.S933F (on ENST00000343002; = p.S666F on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV57969794; called by muse, mutect2, varscan2
- HEXA | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 57/254 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1316178162; called by muse, mutect2, varscan2
- HGF | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.519); catalogued as COSV99738570; called by muse, mutect2, varscan2
- HLA-DQB2 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 66/358 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68615117; called by muse, mutect2, varscan2
- HOXA9 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.2); catalogued as rs1161506915; called by muse, mutect2, varscan2
- HS6ST2 | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs930320430, COSV63717851; called by muse, mutect2, varscan2
- HSF4 | c.536G>A p.G179D | Missense Mutation (SNP) | VAF 105/495 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.172); catalogued as rs377630856; called by muse, varscan2
- HTR1A | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 144/619 reads (23%) | catalogued as COSV60501281; called by muse, mutect2, varscan2
- HYDIN | c.11900C>T p.P3967L | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as rs796605611; called by muse, mutect2, varscan2
- IDUA | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs113373271; called by muse, mutect2, varscan2
- IFT122 | c.571G>A p.E191K (on ENST00000348417 / NM_052989.3; = p.E242K on NM_052985.4) | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.952); catalogued as rs1162709844; called by muse, mutect2, varscan2
- IFT88 | c.2216G>A p.G739D (on ENST00000319980 / NM_001318493.2; = p.G730D on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs772737341; called by muse, mutect2, varscan2
- IGDCC3 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 51/231 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as COSV60077403; called by muse, mutect2, varscan2
- IGHD | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 140/663 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.374); catalogued as rs373899047; called by muse, mutect2, varscan2
- IGKV1D-43 | c.319A>G p.T107A | Missense Mutation (SNP) | VAF 74/372 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as rs558856053; called by muse, mutect2, varscan2
- IGLV10-54 | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as rs564307816, COSV101135416; called by muse, mutect2, varscan2
- IKZF1 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 97/398 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100498866; called by muse, mutect2, varscan2
- IMPG1 | c.498-1G>A p.X166_splice | Splice Site (SNP) | VAF 21/83 reads (25%) | catalogued as rs755923921; called by muse, mutect2, varscan2
- INSL4 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV53328580; called by muse, mutect2, varscan2
- INTS1 | c.2163G>A p.P721= | Splice Region (SNP) | VAF 31/135 reads (23%) | catalogued as rs370270726; called by muse, mutect2, varscan2
- IQCE | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 47/246 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV58080456; called by muse, mutect2, varscan2
- IRX2 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 157/460 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.059); catalogued as COSV57413454; called by muse, mutect2, varscan2
- ITGA9 | c.1931C>T p.T644I | Missense Mutation (SNP) | VAF 78/239 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as rs146299367; called by muse, mutect2, varscan2
- JAKMIP2 | c.1435C>T p.R479* | Nonsense Mutation (SNP) | VAF 20/138 reads (14%) | catalogued as rs772321659, COSV54617673; called by muse, mutect2, varscan2
- JPH3 | c.752G>A p.S251N | Missense Mutation (SNP) | VAF 94/429 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.858); catalogued as rs371378713; called by muse, mutect2, varscan2
- JPH4 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV58115664; called by muse, mutect2, varscan2
- KCNA3 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1355161432; called by muse, mutect2, varscan2
- KCNAB1 | c.923G>A p.G308E (on ENST00000490337 / NM_172160.3; = p.G297E on NM_003471.3) | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV56753872; called by muse, mutect2, varscan2
- KCND3 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 61/282 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56174441; called by muse, mutect2, varscan2
- KCNIP1 | c.244G>A p.E82K (on ENST00000411494 / NM_001034837.3; = p.E71K on NM_014592.4) | Missense Mutation (SNP) | VAF 48/199 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs145371121, COSV61084227; called by muse, mutect2, varscan2
- KCNMA1 | c.2914C>T p.P972S (on ENST00000286628 / NM_001161352.2; = p.P914S on NM_002247.4) | Missense Mutation (SNP) | VAF 58/315 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.901); catalogued as rs794727378; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNN1 | c.124C>T p.L42F | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.203); catalogued as COSV55837494; called by muse, mutect2, varscan2
- KCNQ1 | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 80/274 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as rs946704016, CD097185; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCTD19 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs1268706328; called by muse, mutect2, varscan2
- KIAA1210 | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 82/332 reads (25%) | catalogued as COSV68179910; called by muse, mutect2, varscan2
- KIAA1958 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs756259408; called by muse, mutect2, varscan2
- KIF26B | c.3728C>T p.S1243F | Missense Mutation (SNP) | VAF 59/242 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV63637824; called by muse, mutect2, varscan2
- KIR3DL2 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 77/263 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs1278352539; called by muse, mutect2, varscan2
- KLHL12 | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs573767086, COSV66127334; called by muse, mutect2, varscan2
- KLHL14 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs749190889, COSV100808596, COSV63832501; called by muse, mutect2, varscan2
- KMT2D | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.05); catalogued as rs774098338; called by muse, mutect2, varscan2
- KRT40 | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 30/174 reads (17%) | catalogued as COSV100898823; called by muse, mutect2
- LAMA2 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 49/194 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV70347391; called by muse, mutect2, varscan2
- LGI3 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 71/295 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.333); catalogued as rs866637516, COSV100102964; called by muse, mutect2, varscan2
- LIPI | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs867097666, COSV60709067; called by muse, mutect2, varscan2
- LOXHD1 | c.1610G>A p.R537K | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs1241227633; called by muse, mutect2, varscan2
- LPA | c.4901G>A p.G1634E | Missense Mutation (SNP) | VAF 67/362 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60297995; called by muse, mutect2, varscan2
- LRRC4C | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs1323279700, COSV53423393; called by muse, mutect2, varscan2
- LRRTM3 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as COSV100792017; called by muse, mutect2, varscan2
- LRRTM4 | c.755G>A p.W252* | Nonsense Mutation (SNP) | VAF 29/146 reads (20%) | catalogued as COSV69141233; called by muse, mutect2, varscan2
- LSAMP | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 18/86 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.019); catalogued as COSV100372741; called by muse, mutect2, varscan2
- MAGEA11 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.337); catalogued as COSV60756443; called by muse, varscan2
- MAGEB6 | c.880G>T p.V294L | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs758698861; called by muse, mutect2, varscan2
- MAGI3 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100290041; called by muse, mutect2
- MAP3K14 | c.493C>T p.L165F | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.136); catalogued as rs756661846, COSV60922940; called by muse, mutect2, varscan2
- MCC | c.2062G>A p.G688S | Missense Mutation (SNP) | VAF 59/285 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs141601030; called by muse, mutect2
- MDM4 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs201947927, COSV65795045; called by muse, mutect2, varscan2
- MEFV | c.1760-8C>T | Splice Region (SNP) | VAF 105/458 reads (23%) | catalogued as rs1567231839; ClinVar: likely benign; called by muse, mutect2, varscan2
- MEOX2 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 63/322 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.734); catalogued as rs1170929765, COSV56287672, COSV56288300; called by muse, mutect2, varscan2
- MEP1B | c.1864C>T p.R622* | Nonsense Mutation (SNP) | VAF 27/134 reads (20%) | catalogued as rs201834412, COSV52495894; called by muse, mutect2, varscan2
- MINAR1 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs371598881, COSV59580689; called by muse, mutect2, varscan2
- MMAA | c.823A>G p.I275V | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.164); catalogued as rs764728312; called by muse, mutect2, varscan2
- MME | c.1271G>C p.G424A | Missense Mutation (SNP) | VAF 73/312 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64708843; called by muse, mutect2, varscan2
- MMP16 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV54162306; called by muse, mutect2, varscan2
- MMP24 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 60/268 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as rs1453005203, COSV55769801; called by muse, mutect2, varscan2
- MMP8 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs201312052; called by muse, mutect2, varscan2
- MROH5 | c.2044G>A p.E682K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as COSV101436002; called by muse, mutect2
- MROH5 | c.1915G>A p.G639R | Missense Mutation (SNP) | VAF 70/306 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs774012899; called by muse, mutect2, varscan2
- MROH7 | c.3709C>T p.R1237C | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs747900802, COSV64887264; called by muse, mutect2, varscan2
- MS4A5 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs766740220, COSV55742789; called by muse, mutect2, varscan2
- MSR1 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 57/290 reads (20%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); catalogued as COSV100028288, COSV50513878; called by muse, mutect2, varscan2
- MYBPC2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 90/177 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV63095892; called by muse, mutect2, varscan2
- MYBPHL | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 61/269 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.271); catalogued as COSV64063223; called by muse, mutect2, varscan2
- MYH1 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769113864, COSV56843736; called by muse, mutect2, varscan2
- MYH3 | c.3670G>A p.E1224K | Missense Mutation (SNP) | VAF 89/527 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as rs1177743320, COSV56868963; called by muse, mutect2, varscan2
- MYH6 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 88/346 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV100676761; called by muse, mutect2, varscan2
- MYO15A | c.4597-1G>A p.X1533_splice | Splice Site (SNP) | VAF 104/544 reads (19%) | catalogued as rs1357703648; called by muse, mutect2, varscan2
- MYO15A | c.4597G>A p.E1533K | Missense Mutation (SNP) | VAF 106/547 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1226996756; called by muse, mutect2, varscan2
- MYO5A | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 77/367 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as rs779892139; called by muse, mutect2, varscan2
- MYOM2 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs368565089, COSV50786188; called by muse, mutect2, varscan2
- MYOM3 | c.2780C>T p.S927F | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1266787420; called by muse, mutect2, varscan2
- NAGA | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 78/304 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1296162910; called by muse, mutect2, varscan2
- NANOG | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1281166356; called by muse, mutect2, varscan2
- NCAM1 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57512262; called by muse, mutect2, varscan2
- NCAPH2 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.043); catalogued as rs780370515; called by muse, mutect2, varscan2
- NDST3 | c.1504G>A p.G502R | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56619801; called by muse, mutect2, varscan2
- NELL2 | c.1612G>C p.A538P | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61577484; called by muse, mutect2, varscan2
- NGF | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 74/301 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs566033399, COSV65689105; called by muse, mutect2, varscan2
- NIM1K | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 55/311 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58141819; called by muse, mutect2, varscan2
- NINL | c.2402C>T p.S801L | Missense Mutation (SNP) | VAF 46/223 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.078); catalogued as rs1260605568, COSV54002084; called by muse, mutect2, varscan2
- NINL | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as rs1568931939; called by muse, mutect2, varscan2
- NINL | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV54002163; called by muse, mutect2, varscan2
- NLRP3 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 90/378 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV60230994; called by muse, mutect2, varscan2
- NLRP7 | c.628C>T p.L210F | Missense Mutation (SNP) | VAF 99/202 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750084751; called by muse, mutect2, varscan2
- NOC2L | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs755202760; called by muse, mutect2, varscan2
- NOL4 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as rs764755868, COSV52357990; called by muse, mutect2, varscan2
- NOMO1 | c.2707C>T p.R903C | Missense Mutation (SNP) | VAF 64/365 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1357773385, COSV55057659, COSV99814442; called by muse, mutect2, varscan2
- NOTCH1 | c.4579C>T p.Q1527* | Nonsense Mutation (SNP) | VAF 110/493 reads (22%) | catalogued as COSV53032614; called by muse, mutect2, varscan2
- NOTCH1 | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 121/511 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1266989706, COSV53039240; called by muse, mutect2, varscan2
- NOTCH2 | c.6259C>T p.P2087S | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV56698253; called by muse, mutect2, varscan2
- NPAP1 | c.1568C>T p.S523F | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as rs868778749, COSV61509982; called by muse, varscan2
- NPAP1 | c.1597C>T p.L533F | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.914); catalogued as rs764897370, COSV61505209, COSV61511306; called by muse, varscan2
- NPR3 | c.1499C>A p.A500D (on ENST00000265074 / NM_001364458.2; = p.A499D on NM_000908.4) | Missense Mutation (SNP) | VAF 51/376 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM1210966; called by muse, mutect2, varscan2
- NRAP | c.2143G>A p.E715K (on ENST00000359988 / NM_001322945.2; = p.E680K on NM_006175.4) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs746844785, COSV100748604, COSV63488332; called by muse, mutect2, varscan2
- NT5DC3 | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.87); PolyPhen benign (0.01); catalogued as COSV67323144; called by muse, mutect2, varscan2
- NTS | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763411650; called by muse, mutect2, varscan2
- NUAK1 | c.1327C>T p.P443S | Missense Mutation (SNP) | VAF 62/263 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1458873105, COSV54601616; called by muse, mutect2, varscan2
- NUP205 | c.2433T>G p.N811K | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); catalogued as COSV53659359; called by muse, mutect2, varscan2
- NUP210L | c.4601G>C p.G1534A | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55158180; called by muse, mutect2, varscan2
- OAS2 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 29/131 reads (22%) | catalogued as COSV60804335; called by muse, mutect2, varscan2
- OBSCN | c.8431G>T p.V2811L | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as rs781743737; called by muse, mutect2, varscan2
- OCRL | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 80/309 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV63980401; called by muse, mutect2, varscan2
- OLFML2A | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 54/233 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.216); catalogued as rs548410915; called by muse, mutect2, varscan2
- OPA1 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 50/220 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.259); catalogued as rs1417008261; called by muse, mutect2, varscan2
- OR13C9 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV52243756; called by muse, mutect2, varscan2
- OR13D1 | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV100598758; called by muse, mutect2, varscan2
- OR2L13 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 78/301 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV63558072, COSV63561266; called by muse, mutect2, varscan2
- OR4C16 | c.288G>A p.M96I | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1565052193, COSV58942866; called by muse, mutect2, varscan2
- OR4C6 | c.863G>A p.R288K | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.914); catalogued as rs12363829; called by muse, mutect2, varscan2
- OR4D6 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.16); catalogued as rs765537042, COSV55659748; called by muse, mutect2, varscan2
- OR51A7 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1292332174; called by muse, mutect2, varscan2
- OR5D13 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100686737; called by muse, mutect2, varscan2
- OR5D14 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV100162591, COSV59455986; called by muse, mutect2, varscan2
- OR5I1 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs867942038, COSV56888486; called by muse, mutect2
- OR5I1 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56886245; called by muse, mutect2, varscan2
- OR5R1 | c.841G>T p.V281L | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs756180609; called by muse, mutect2, varscan2
- OR8B12 | c.812A>T p.K271I | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV60910929; called by muse, mutect2, varscan2
- OR8I2 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777929505, COSV56167693; called by muse, mutect2, varscan2
- OSMR | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 53/268 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.284); catalogued as COSV57090569; called by muse, mutect2, varscan2
- PAK1 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1233155113, COSV53698661, COSV99583000; called by muse, mutect2, varscan2
- PAPPA | c.4157C>T p.S1386F | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs929769049, COSV60288527; called by muse, mutect2, varscan2
- PARD3 | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60763164; called by muse, mutect2, varscan2
- PARD6A | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54670952; called by muse, mutect2, varscan2
- PCDH11X | c.1249C>T p.L417F | Missense Mutation (SNP) | VAF 76/401 reads (19%) | SIFT tolerated (0.73); PolyPhen probably damaging (1); catalogued as COSV53489302; called by muse, mutect2, varscan2
- PCDH15 | c.4375C>T p.L1459F | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.077); catalogued as rs146455585; called by muse, mutect2, varscan2
- PCDH15 | c.1645C>T p.L549F | Missense Mutation (SNP) | VAF 63/312 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV57312185, COSV57372906; called by muse, mutect2, varscan2
- PCDH15 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 64/272 reads (24%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.986); catalogued as rs767966376, COSV57263373; called by muse, mutect2, varscan2
- PCDH17 | c.1177G>A p.G393S | Missense Mutation (SNP) | VAF 96/268 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.965); catalogued as COSV64973341; called by muse, mutect2, varscan2
- PCDHA11 | c.626A>G p.N209S | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.014); catalogued as rs1554163384; called by muse, mutect2, varscan2
- PCDHB5 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 83/328 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.732); catalogued as rs374862933, COSV50664345; called by muse, mutect2, varscan2
- PCDHB6 | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 134/702 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV50690715; called by muse, varscan2
- PCDHGA4 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV54043124; called by muse, mutect2, varscan2
- PCDHGA6 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs745902303; called by muse, mutect2, varscan2
- PCLO | c.6454G>A p.E2152K | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV61636627; called by muse, mutect2, varscan2
- PDHA2 | c.1112C>T p.S371L | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV54778748; called by muse, mutect2, varscan2
- PDLIM5 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs1179075912; called by muse, mutect2, varscan2
- PDPK1 | c.1651C>T p.P551S | Missense Mutation (SNP) | VAF 62/239 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV51913207; called by muse, mutect2, varscan2
- PDZRN3 | c.2534G>A p.G845E | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs926613280; called by muse, mutect2, varscan2
- PHKA2 | c.1252C>T p.L418F | Missense Mutation (SNP) | VAF 43/223 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1361135983; called by muse, mutect2, varscan2
- PIGG | c.2033G>A p.W678* (on ENST00000453061 / NM_001127178.3; = p.W670* on NM_017733.4) | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as rs1292836567; called by muse, mutect2, varscan2
- PIGN | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.027); catalogued as rs1309292173; called by muse, mutect2, varscan2
- PIM2 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 81/366 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.41); catalogued as rs782504114; called by muse, mutect2, varscan2
- PKD1 | c.8965G>A p.G2989R | Missense Mutation (SNP) | VAF 104/553 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0.006); catalogued as rs1359870594; called by muse, mutect2, varscan2
- PKD2L1 | c.488G>A p.G163D | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.861); catalogued as COSV58395880; called by muse, varscan2
- PKHD1 | c.1384G>T p.A462S | Missense Mutation (SNP) | VAF 68/379 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as rs758984026, COSV100580815; called by muse, mutect2, varscan2
- PKHD1L1 | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.167); catalogued as COSV65755276; called by muse, mutect2, varscan2
- PKN3 | c.1584G>A p.P528= | Splice Region (SNP) | VAF 22/80 reads (28%) | catalogued as rs1317952953, COSV52579981; called by muse, mutect2, varscan2
- PLCB4 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV53793204; called by muse, mutect2, varscan2
- PLCE1 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 87/309 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV53342427; called by muse, mutect2, varscan2
- PLCXD2 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 58/250 reads (23%) | catalogued as rs571921225, COSV67341126; called by muse, mutect2, varscan2
- PLCXD3 | c.406C>T p.H136Y | Missense Mutation (SNP) | VAF 72/219 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs765853658; called by muse, mutect2, varscan2
- PLEKHG3 | c.2933C>T p.S978F (on ENST00000394691; = p.S1034F on NM_001308147.2) | Missense Mutation (SNP) | VAF 120/391 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.509); catalogued as COSV55977682; called by muse, mutect2, varscan2
- PLOD3 | c.1233-1G>A p.X411_splice | Splice Site (SNP) | VAF 40/165 reads (24%) | catalogued as rs1305000842; called by muse, mutect2, varscan2
- PLXNA4 | c.4144G>A p.D1382N | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs118107843, COSV58134136; called by muse, mutect2, varscan2
- PLXNA4 | c.3319C>T p.H1107Y | Missense Mutation (SNP) | VAF 90/406 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.31); catalogued as rs765370862; called by muse, mutect2, varscan2
- PMFBP1 | c.1783C>T p.R595C (on ENST00000537465; = p.R590C on NM_031293.3) | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as rs149578677, COSV99401367; called by muse, mutect2, varscan2
- POTEG | c.318C>A p.F106L | Missense Mutation (SNP) | VAF 136/1854 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs746550954; called by muse, mutect2
- POU6F2 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV68867228; called by muse, mutect2, varscan2
- PPP1R10 | c.2462G>A p.G821E | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs574591989, COSV64739986; called by muse, mutect2, varscan2
- PPP1R10 | c.2461G>A p.G821R | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.063); catalogued as rs756919628, COSV64738382; called by muse, mutect2, varscan2
- PPP1R26 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100777986; called by muse, mutect2, varscan2
- PPP6R2 | c.2786G>A p.G929E (on ENST00000216061 / NM_001365836.1; = p.G895E on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs752517704; called by muse, mutect2, varscan2
- PRB2 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV101231406; called by muse, varscan2
- PRDM1 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.075); catalogued as COSV64844831; called by muse, varscan2
- PRDM1 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 57/234 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.11); catalogued as rs1562173276; called by muse, varscan2
- PRDM16 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 77/254 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1452901414, COSV54578558; called by muse, mutect2, varscan2
- PRDM4 | c.1186T>A p.F396I | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.79); catalogued as rs1566096440; called by muse, mutect2, varscan2
- PREX1 | c.3020C>G p.P1007R | Missense Mutation (SNP) | VAF 47/235 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV64249684; called by muse, mutect2, varscan2
- PRICKLE3 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 47/224 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV54294617; called by muse, mutect2, varscan2
- PRKAA1 | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.129); catalogued as rs1033125825, COSV57184305; called by muse, mutect2, varscan2
- PRKCA | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.742); catalogued as COSV52579991; called by muse, mutect2, varscan2
- PRKCB | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57773941; called by muse, mutect2, varscan2
- PRKG1 | c.494T>C p.V165A | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64793412; called by muse, mutect2, varscan2
- PRR30 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 105/408 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.495); catalogued as COSV53206152; called by muse, mutect2, varscan2
- PRRC2B | c.3194G>A p.R1065Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs553258692, COSV61937703; called by muse, mutect2, varscan2
- PRRT4 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.577); catalogued as rs373427991; called by muse, mutect2, varscan2
- PSTPIP1 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs776576205, COSV51201259; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- PTGDR2 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 98/443 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.624); catalogued as rs761350678; called by muse, mutect2, varscan2
- PTPRB | c.3874G>A p.D1292N | Missense Mutation (SNP) | VAF 56/281 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.924); catalogued as rs1250884124, COSV54242050; called by muse, mutect2, varscan2
- PTPRF | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV63443460, COSV63444547; called by muse, mutect2, varscan2
- PTPRM | c.1627G>A p.G543R | Missense Mutation (SNP) | VAF 45/243 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.726); catalogued as COSV59866504; called by muse, mutect2, varscan2
- PTPRQ | c.2974G>A p.D992N (on ENST00000616559; = p.D950N on NM_001145026.2) | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1159623687, COSV57047500, COSV57056021; called by muse, mutect2, varscan2
- QRICH1 | c.2105C>T p.P702L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV100455092, COSV58707537; called by muse, mutect2, varscan2
- RADIL | c.1201C>T p.R401W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs1412106903; called by muse, mutect2, varscan2
- RBM15 | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs768852717; called by muse, mutect2, varscan2
- REG1B | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 87/297 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs372283770, COSV100521220, COSV59308357; called by muse, mutect2, varscan2
- REG3G | c.186G>A p.M62I | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs267599466, COSV55451136; called by muse, mutect2, varscan2
- RGS17 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52806961; called by muse, mutect2, varscan2
- RHCG | c.1172G>T p.G391V | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as COSV51514575; called by muse, mutect2, varscan2
- RIMS2 | c.1423G>A p.E475K (on ENST00000666250 / NM_001348490.2; = p.E283K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/254 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs866320106, COSV51670109; called by muse, mutect2, varscan2
- RNF151 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs759624678; called by muse, mutect2, varscan2
- ROS1 | c.5788A>G p.T1930A | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV63856414; called by muse, mutect2, varscan2
- RPL11 | c.221G>A p.R74Q (on ENST00000374550 / NM_001199802.1; = p.R75Q on NM_000975.5) | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.427); catalogued as rs200331226; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPL3L | c.55C>T p.H19Y | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV51908392; called by muse, mutect2, varscan2
- RPS6KA6 | c.1624C>T p.R542C | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs139038048, COSV53123540; called by muse, mutect2
- RYR2 | c.94C>A p.Q32K | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.203); catalogued as rs1553373926; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- S100PBP | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV100758409; called by muse, mutect2, varscan2
- SAG | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1237999640, COSV68591505; called by muse, mutect2, varscan2
- SCN1A | c.5657G>A p.R1886Q (on ENST00000303395 / NM_001202435.3; = p.R1875Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as rs1559100385, CD031887, CM134117, COSV57665487; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN8A | c.2926C>T p.L976F | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61976412; called by muse, mutect2, varscan2
- SCN9A | c.3863C>T p.S1288F (on ENST00000303354; = p.S1277F on NM_002977.3) | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57601215; called by muse, mutect2, varscan2
- SCNN1G | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 72/282 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs147199706; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC16B | c.2197A>G p.T733A | Missense Mutation (SNP) | VAF 56/257 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1436001119; called by muse, mutect2, varscan2
- SEZ6L2 | c.499G>A p.V167M (on ENST00000308713 / NM_001114099.3; = p.V97M on NM_012410.4) | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.969); catalogued as COSV58097851; called by muse, mutect2, varscan2
- SH3TC2 | c.2894C>T p.S965F | Missense Mutation (SNP) | VAF 86/382 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1220087441; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHANK3 | c.3631G>A p.G1211R | Missense Mutation (SNP) | VAF 101/390 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs754607187; called by muse, mutect2, varscan2
- SHROOM2 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV66605416; called by muse, mutect2, varscan2
- SIGLEC1 | c.1459G>A p.G487R | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1442047982; called by muse, mutect2, varscan2
- SIM1 | c.1174G>A p.G392R | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.697); catalogued as COSV53489208, COSV53492190; called by muse, mutect2, varscan2
- SIN3A | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64583958; called by muse, mutect2, varscan2
- SIPA1L3 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs773660155; called by muse, mutect2, varscan2
- SKAP1 | c.180G>A p.G60= | Splice Region (SNP) | VAF 21/84 reads (25%) | catalogued as rs764249578, COSV61146016; called by muse, mutect2, varscan2
- SLC25A39 | c.517+1G>A p.X173_splice (on ENST00000377095 / NM_001143780.3; = p.X165_splice on NM_016016.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 63/225 reads (28%) | catalogued as rs781187206, COSV99835233; called by muse, mutect2, varscan2
- SLC25A48 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs758384952, COSV99192133; called by muse, mutect2, varscan2
- SLC2A10 | c.1547G>A p.R516Q | Missense Mutation (SNP) | VAF 71/313 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs760437795; called by muse, mutect2
- SLC38A5 | c.132C>T p.F44= | Splice Region (SNP) | VAF 19/112 reads (17%) | catalogued as rs1183011922, COSV58333214; called by muse, mutect2, varscan2
- SLC6A19 | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 389/777 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as rs778071659; called by muse, mutect2, varscan2
- SLC6A3 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 116/851 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as rs745426965, COSV99548502; called by muse, mutect2, varscan2
- SLC7A6OS | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV50449943; called by muse, mutect2, varscan2
- SLFN13 | c.2269C>T p.P757S | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs1443901331; called by muse, mutect2, varscan2
- SMAD9 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 93/416 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs982801394; called by muse, mutect2, varscan2
- SORCS1 | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 67/310 reads (22%) | SIFT tolerated, low confidence (0.59); PolyPhen possibly damaging (0.496); catalogued as rs773702730; called by muse, mutect2, varscan2
- SORCS3 | c.939C>A p.Y313* | Nonsense Mutation (SNP) | VAF 27/84 reads (32%) | catalogued as COSV63825409; called by muse, mutect2, varscan2
- SPATA13 | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 62/200 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as COSV66066104; called by muse, mutect2, varscan2
- SPOPL | c.192A>T p.K64N | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as COSV99699808; called by muse, mutect2, varscan2
- SRRM1 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV100105032; called by muse, mutect2, varscan2
- SSC5D | c.2066C>T p.P689L | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.078); catalogued as rs751190661; called by muse, mutect2, varscan2
- SSTR4 | c.895C>T p.L299F | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs965077763; called by muse, mutect2, varscan2
- SYNE2 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 100/204 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs373286353; called by muse, mutect2, varscan2
- TAL1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV53747098, COSV99595824; called by muse, mutect2, varscan2
- TBC1D24 | c.1675C>T p.Q559* (on ENST00000646147 / NM_001199107.2; = p.Q553* on NM_020705.3) | Nonsense Mutation (SNP) | VAF 59/248 reads (24%) | catalogued as rs1253505916, COSV53545247; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBC1D8B | c.1939C>T p.L647F | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778624354; called by muse, mutect2, varscan2
- TCHH | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 58/250 reads (23%) | catalogued as COSV64274679; called by muse, mutect2, varscan2
- TDRD1 | c.2479C>T p.R827W | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs866270956, COSV52590715; called by muse, mutect2
- TENT5C | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV65615893; called by muse, mutect2, varscan2
- TET3 | c.4601C>T p.P1534L | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as rs368037344; called by muse, mutect2, varscan2
- TEX15 | c.4040G>A p.G1347E (on ENST00000256246; = p.G1730E on NM_001350162.2) | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs866055420, COSV56341603; called by muse, mutect2, varscan2
- TEX15 | c.1531G>A p.E511K (on ENST00000256246; = p.E894K on NM_001350162.2) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs267601898, COSV56341254; called by muse, mutect2, varscan2
- THSD7A | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 93/349 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV70275069; called by muse, mutect2, varscan2
- TMC3 | c.2395G>A p.D799N | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs755012180; called by muse, mutect2, varscan2
- TMC5 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 72/322 reads (22%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as rs369805960; called by muse, mutect2, varscan2
- TMCC2 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs1293253975; called by muse, mutect2
- TMEM132A | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 64/260 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.009); catalogued as rs149956203; called by muse, mutect2, varscan2
- TMEM45B | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV99859192; called by muse, mutect2, varscan2
- TNFRSF21 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 94/356 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.046); catalogued as rs772690932, COSV57280822; called by muse, mutect2, varscan2
- TNFSF10 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53842912; called by muse, mutect2, varscan2
- TNR | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 54/255 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs865799348; called by muse, mutect2, varscan2
- TNRC6B | c.4807C>T p.P1603S (on ENST00000454349 / NM_001162501.2; = p.P1493S on NM_015088.3) | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57292993; called by muse, mutect2, varscan2
- TNXB | c.2762C>T p.S921F | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs776729068; called by muse, mutect2, varscan2
- TOX2 | c.505C>T p.R169C (on ENST00000358131 / NM_001098798.2; = p.R118C on NM_032883.3) | Missense Mutation (SNP) | VAF 74/255 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1458899028, COSV57886169; called by muse, mutect2, varscan2
- TP53BP1 | c.874C>T p.Q292* | Nonsense Mutation (SNP) | VAF 39/153 reads (25%) | catalogued as COSV55498556; called by muse, mutect2, varscan2
- TRAF5 | c.1070C>T p.T357I | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as rs1177783041; called by muse, mutect2, varscan2
- TRIM42 | c.1068G>A p.M356I | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs759172731; called by muse, varscan2
- TRRAP | c.7278-1G>A p.X2426_splice (on ENST00000359863 / NM_001244580.1; = p.X2408_splice on NM_003496.3) | Splice Site (SNP) | VAF 55/187 reads (29%) | catalogued as COSV62852132; called by muse, mutect2
- TSPYL5 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as COSV100438930; called by muse, mutect2, varscan2
- TUBA4B | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 67/182 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs3896929; called by muse, mutect2, varscan2
- TYR | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 68/278 reads (24%) | SIFT tolerated (0.92); PolyPhen benign (0.045); catalogued as rs896650424, COSV54483223, COSV99635242; called by muse, mutect2, varscan2
- UGT2B4 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.102); catalogued as rs762160995; called by muse, mutect2, varscan2
- USP29 | c.2177G>A p.G726E | Missense Mutation (SNP) | VAF 84/157 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.063); catalogued as COSV54145893; called by muse, mutect2, varscan2
- USP6 | c.1211C>T p.S404F | Missense Mutation (SNP) | VAF 177/642 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.485); catalogued as COSV51496651; called by muse, mutect2, varscan2
- VIT | c.1943C>T p.S648F (on ENST00000389975 / NM_001177969.1; = p.S663F on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/268 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs1553384960; called by muse, mutect2, varscan2
- VWA5A | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs867374152, COSV100795745; called by muse, mutect2, varscan2
- WDR24 | c.631G>T p.D211Y (on ENST00000248142; = p.D149Y on NM_032259.4) | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50202608; called by muse, mutect2, varscan2
- WDR64 | c.3071G>A p.R1024K | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV63794942; called by muse, mutect2, varscan2
- WDR72 | c.1686G>A p.M562I | Missense Mutation (SNP) | VAF 53/242 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV100854770; called by muse, mutect2, varscan2
- WFDC1 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1459470816, COSV54745627; called by muse, mutect2, varscan2
- WSCD1 | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 93/348 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV100496491; called by muse, mutect2, varscan2
- WWC3 | c.3070G>A p.E1024K | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.92); catalogued as COSV66506124; called by muse, mutect2, varscan2
- ZAN | c.2941G>A p.E981K | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as COSV61816238; called by muse, varscan2
- ZFP3 | c.1426C>T p.P476S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773587855, COSV59584495; called by muse, mutect2, varscan2
- ZFP41 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 62/221 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); catalogued as COSV58085992, COSV58086935; called by muse, mutect2, varscan2
- ZFYVE16 | c.1193T>C p.L398S | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.702); catalogued as rs1376108934; called by muse, mutect2, varscan2
- ZFYVE16 | c.3230C>T p.S1077F | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as rs1381170305; called by muse, mutect2, varscan2
- ZIC2 | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs758514066; called by muse, mutect2, varscan2
- ZMAT1 | c.735G>A p.M245I | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.099); catalogued as rs1238496181; called by muse, mutect2, varscan2
- ZNF148 | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62301979; called by muse, mutect2, varscan2
- ZNF189 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.78); catalogued as rs749809299, COSV52275204; called by muse, mutect2, varscan2
- ZNF221 | c.905G>A p.R302K | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.565); catalogued as rs557392063, COSV52108750; called by muse, mutect2, varscan2
- ZNF23 | c.1928C>T p.S643F | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.372); catalogued as COSV100612071; called by muse, mutect2, varscan2
- ZNF256 | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as rs1011268320; called by muse, mutect2, varscan2
- ZNF331 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 66/222 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs765490388; called by muse, mutect2, varscan2
- ZNF570 | c.1306C>T p.H436Y | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57578087; called by muse, varscan2
- ZNF630 | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.933); catalogued as rs782499467; called by muse, mutect2, varscan2
- ZNF737 | c.1507C>T p.H503Y | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.227); catalogued as COSV71199470; called by muse, mutect2, varscan2
- ZNF804A | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs767729735; called by muse, mutect2, varscan2
- ZNF835 | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 71/387 reads (18%) | catalogued as rs755173314; called by muse, mutect2, varscan2
- ZNF93 | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as rs754715493; called by muse, varscan2
- ZPLD1 | c.103C>T p.P35S (on ENST00000466937 / NM_001329788.1; = p.P51S on NM_175056.2) | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs139525039, COSV60356765; called by muse, mutect2, varscan2
- ABCC3 | c.675-7C>T | Splice Region (SNP) | VAF 47/142 reads (33%) | called by muse, mutect2, varscan2
- ACOT12 | c.665G>A p.W222* | Nonsense Mutation (SNP) | VAF 30/161 reads (19%) | called by muse, mutect2, varscan2
- ACSM2A | c.1696A>G p.K566E (on ENST00000219054; = p.K487E on NM_001308169.2) | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- ADAM12 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADAMTS12 | c.3425C>T p.P1142L | Missense Mutation (SNP) | VAF 231/408 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ADAMTS15 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.8); PolyPhen benign (0.013); called by muse, mutect2
- ADARB2 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, mutect2
- ADGRG4 | c.7043A>T p.K2348I | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ADHFE1 | c.837T>G p.S279R | Missense Mutation (SNP) | VAF 62/231 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AEBP1 | c.668-1G>A p.X223_splice | Splice Site (SNP) | VAF 41/162 reads (25%) | called by muse, mutect2, varscan2
- AFF3 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGO4 | c.325C>T p.L109F | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.027); called by muse, mutect2
- AGRN | c.886T>G p.C296G | Missense Mutation (SNP) | VAF 74/233 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- AGTR1 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGTR2 | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGXT2 | c.34T>G p.L12V | Missense Mutation (SNP) | VAF 198/379 reads (52%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- AHNAK | c.9761A>G p.D3254G | Missense Mutation (SNP) | VAF 61/277 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AKAP4 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ALAD | c.397+8C>T | Splice Region (SNP) | VAF 55/241 reads (23%) | called by muse, mutect2, varscan2
- ALG10 | c.1057C>A p.H353N | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALG2 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 74/333 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ALMS1 | c.8956C>T p.P2986S | Missense Mutation (SNP) | VAF 49/220 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- ALOX12B | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 122/429 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- AMOTL1 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ANK2 | c.6094G>A p.E2032K | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANKRD11 | c.6364G>A p.D2122N | Missense Mutation (SNP) | VAF 65/246 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- ANKRD34B | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- ANKRD34C | c.1602G>A p.M534I | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD55 | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANKS6 | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- ANO9 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.71); called by mutect2, varscan2
- ANXA9 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- APLF | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- APOB | c.7578G>A p.M2526I | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ARFGEF3 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ARHGAP26 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ARHGAP36 | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARMC4 | c.2051G>A p.S684N | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- ARNTL2 | c.452G>A p.R151K | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ASXL2 | c.3115T>A p.F1039I | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- AXDND1 | c.1595G>A p.G532E | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BCO1 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 77/373 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- BCO2 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- BCO2 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- BICC1 | c.2165C>T p.S722L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- BMPER | c.1609C>T p.P537S | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- BMPER | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- BOD1L1 | c.8993C>T p.P2998L | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- BPIFB1 | c.230T>G p.V77G | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- BST1 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- C11orf1 | c.344-2A>T p.X115_splice | Splice Site (SNP) | VAF 38/202 reads (19%) | called by muse, mutect2, varscan2
- C12orf43 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 53/181 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- C15orf61 | c.53G>A p.R18K | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- C16orf54 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.648); called by muse, mutect2
- C18orf63 | c.1536A>C p.Q512H | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- C3orf80 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated, low confidence (0.72); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- C4B | c.3948G>A p.W1316* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | called by mutect2, varscan2
- CACNA1E | c.5833G>A p.D1945N | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2
- CACNA1H | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 106/403 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1S | c.4921C>G p.P1641A | Missense Mutation (SNP) | VAF 76/323 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- CAMTA2 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 54/231 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CAPN14 | c.1052C>T p.T351I | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- CASKIN1 | c.1589G>A p.S530N | Missense Mutation (SNP) | VAF 62/319 reads (19%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC15 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CCDC168 | c.6456G>A p.M2152I | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CCDC88A | c.1528C>T p.L510F | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCER2 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CD247 | c.162+6T>A | Splice Region (SNP) | VAF 62/358 reads (17%) | called by muse, mutect2, varscan2
- CD46 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD69 | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- CD8B | c.547C>G p.L183V | Missense Mutation (SNP) | VAF 56/199 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CDADC1 | c.845T>C p.L282P | Missense Mutation (SNP) | VAF 90/231 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- CDH10 | c.1561G>A p.G521R | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CDH11 | c.643+1G>T p.X215_splice | Splice Site (SNP) | VAF 45/129 reads (35%) | called by muse, mutect2, varscan2
- CDH17 | c.1940T>C p.L647S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CDH23 | c.3221-1G>A p.X1074_splice | Splice Site (SNP) | VAF 22/83 reads (27%) | called by muse, mutect2, varscan2
- CDH4 | c.1497G>A p.M499I | Missense Mutation (SNP) | VAF 112/495 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CEP128 | c.1525G>T p.E509* | Nonsense Mutation (SNP) | VAF 13/120 reads (11%) | called by muse, varscan2
- CEP152 | c.4232C>T p.P1411L (on ENST00000380950 / NM_001194998.2; = p.P1355L on NM_014985.4) | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- CEP57L1 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP95 | c.1051T>A p.C351S | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CFAP54 | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- CFAP74 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 70/196 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- CHD5 | c.2093G>A p.G698D | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHRM4 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CHST9 | c.974G>A p.G325E | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CKAP2 | c.695G>A p.R232K (on ENST00000378037 / NM_001098525.2; = p.R231K on NM_018204.5) | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- CLNK | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CLSTN2 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLUH | c.179T>C p.F60S (on ENST00000435359; = p.F98S on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, varscan2
- CLUL1 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- CMKLR1 | c.773C>T p.P258L (on ENST00000312143 / NM_001142344.2; = p.P256L on NM_004072.3) | Missense Mutation (SNP) | VAF 55/215 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CNGA2 | c.47A>C p.H16P | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CNGB1 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 67/323 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CNKSR2 | c.2027G>A p.R676K | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.96); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CNTN3 | c.2244G>A p.W748* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.1177T>A p.F393I | Missense Mutation (SNP) | VAF 111/421 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL11A1 | c.2323G>A p.G775R | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL11A2 | c.3323G>A p.G1108E (on ENST00000341947 / NM_080680.3; = p.G1001E on NM_080679.2) | Missense Mutation (SNP) | VAF 70/338 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- COL14A1 | c.1456G>A p.D486N | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- COL1A1 | c.2622dup p.G875Wfs*38 | Frame Shift Ins (INS) | VAF 89/500 reads (18%) | called by pindel, varscan2
- COL5A1 | c.5324C>T p.S1775F | Missense Mutation (SNP) | VAF 70/297 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL6A6 | c.4535G>A p.G1512E | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A6 | c.4984G>A p.G1662R | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPM | c.375G>A p.M125I | Missense Mutation (SNP) | VAF 64/247 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CRB1 | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 59/235 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CRELD1 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.87); called by muse, mutect2
- CRNKL1 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 59/305 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSMD1 | c.5513G>A p.G1838D (on ENST00000520002; = p.G1837D on NM_033225.6) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD2 | c.6290C>A p.T2097N | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSMD3 | c.6131A>T p.Y2044F (on ENST00000297405 / NM_001363185.1; = p.Y1940F on NM_052900.3) | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CSNK2A2 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 44/265 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- CSRNP1 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CTNND2 | c.2048C>A p.T683N | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- CUL2 | c.2006G>A p.R669K | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- CUX2 | c.2435C>T p.S812F | Missense Mutation (SNP) | VAF 86/430 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- CYP11B1 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 87/326 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CYP27A1 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 102/319 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CYP2R1 | c.1382T>G p.F461C | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP4B1 | c.1237C>T p.H413Y | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DCC | c.1889C>T p.S630F | Missense Mutation (SNP) | VAF 92/373 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- DCHS1 | c.6251G>A p.G2084E | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DENND2A | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DENR | c.129C>T p.Y43= | Splice Region (SNP) | VAF 26/140 reads (19%) | called by muse, mutect2, varscan2
- DGKB | c.332T>G p.M111R | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- DGKH | c.896C>G p.P299R | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- DHX9 | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- DIAPH2 | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIPK2B | c.963C>T p.G321= | Splice Region (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2
- DLGAP1 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- DLGAP2 | c.3092C>T p.S1031F | Missense Mutation (SNP) | VAF 73/335 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH17 | c.3735G>A p.M1245I | Missense Mutation (SNP) | VAF 59/195 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- DNAH17 | c.3242G>A p.G1081D | Missense Mutation (SNP) | VAF 53/214 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- DNAH6 | c.1409A>T p.K470M | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- DNAH6 | c.4984G>A p.E1662K | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- DNAH8 | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH9 | c.11090C>T p.P3697L | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- DOCK11 | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 45/287 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DOCK2 | c.1568G>A p.G523E | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- DPPA3 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 116/442 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DSCAML1 | c.2455G>A p.E819K (on ENST00000321322; = p.E759K on NM_020693.4) | Missense Mutation (SNP) | VAF 54/320 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- DUSP8 | c.1148G>C p.R383P | Missense Mutation (SNP) | VAF 65/294 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- DYNC1LI2 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- EDEM2 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- EDNRA | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EEF2K | c.637T>C p.C213R | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- EFEMP1 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 90/350 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- EIF3E | c.430T>A p.Y144N | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- EIF4A3 | c.375G>A p.G125= | Splice Region (SNP) | VAF 25/97 reads (26%) | called by muse, mutect2, varscan2
- EIF4G3 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.497); called by muse, mutect2
- EP300 | c.3076G>A p.E1026K | Missense Mutation (SNP) | VAF 50/253 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- EPHA2 | c.1268C>T p.T423I | Missense Mutation (SNP) | VAF 89/269 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPX | c.1058A>G p.N353S | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ERCC6L | c.142A>G p.K48E | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- ESYT2 | c.1455A>T p.L485F (on ENST00000613624; = p.L409F on NM_020728.3) | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- EXOC4 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- EXOSC9 | c.779A>C p.E260A | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- F5 | c.2995C>T p.P999S | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- F8 | c.6157G>A p.D2053N | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- F8A1 | c.1094C>T p.S365F | Missense Mutation (SNP) | VAF 56/766 reads (7%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.461); called by muse, mutect2
- FADS6 | c.326C>T p.T109I | Missense Mutation (SNP) | VAF 58/318 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM124A | c.776C>T p.P259L (on ENST00000322475 / NM_001242312.2; = p.P295L on NM_145019.4) | Missense Mutation (SNP) | VAF 47/260 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM214A | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 52/286 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM3A | c.152-8C>T | Splice Region (SNP) | VAF 62/246 reads (25%) | called by muse, mutect2, varscan2
- FAM53C | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- FAM83E | c.1276C>G p.P426A | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FANCA | c.2726C>T p.S909F | Missense Mutation (SNP) | VAF 75/368 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- FAS | c.62A>G p.K21R | Missense Mutation (SNP) | VAF 72/279 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FBP1 | c.706-1G>A p.X236_splice | Splice Site (SNP) | VAF 67/310 reads (22%) | called by muse, mutect2, varscan2
- FBXL7 | c.397C>A p.Q133K | Missense Mutation (SNP) | VAF 252/525 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- FCAMR | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- FGF14 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 65/216 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- FIG4 | c.1613G>A p.G538D | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FIGNL2 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- FLG | c.9343G>A p.G3115R | Missense Mutation (SNP) | VAF 116/505 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- FLNB | c.5797A>G p.T1933A | Missense Mutation (SNP) | VAF 65/227 reads (29%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- FMN2 | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 47/216 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- FOXM1 | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- FOXM1 | c.1885C>T p.P629S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- FOXO4 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 81/213 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FRG2C | c.782C>G p.P261R | Missense Mutation (SNP) | VAF 30/479 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- FRMPD1 | c.3041C>T p.S1014F | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- FRMPD4 | c.2639C>T p.S880F | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- FRS3 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FSIP2 | c.7229G>A p.C2410Y | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSIP2 | c.19838G>A p.R6613K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GAB2 | c.839G>A p.G280D (on ENST00000361507 / NM_080491.3; = p.G242D on NM_012296.3) | Missense Mutation (SNP) | VAF 108/540 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GAB2 | c.838G>A p.G280S (on ENST00000361507 / NM_080491.3; = p.G242S on NM_012296.3) | Missense Mutation (SNP) | VAF 110/539 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRB2 | c.497G>A p.R166K | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GABRG3 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- GABRQ | c.1846C>T p.P616S | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.554); called by muse, mutect2
- GABRR3 | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- GALM | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GALNT15 | c.539+1G>A p.X180_splice | Splice Site (SNP) | VAF 6/15 reads (40%) | called by muse, varscan2
- GAS7 | c.565G>A p.E189K (on ENST00000432992 / NM_201433.2; = p.E49K on NM_003644.3) | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- GDF9 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 85/325 reads (26%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- GDPD2 | c.284C>A p.T95K | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GGCX | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- GGN | c.1508C>T p.T503I | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- GLI2 | c.3736C>T p.L1246F (on ENST00000361492 / NM_001374353.1; = p.L1263F on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- GLS2 | c.1288G>A p.G430R | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLYAT | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- GOLGA6A | c.1426-6C>T | Splice Region (SNP) | VAF 92/1114 reads (8%) | called by muse, mutect2
- GOLGA6L6 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 40/434 reads (9%) | called by muse, mutect2, varscan2
- GPATCH11 | c.664G>A p.E222K (on ENST00000409774; = p.E200K on NM_174931.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- GPR75 | c.1613C>T p.P538L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- GREB1 | c.4501G>A p.E1501K | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GRHL3 | c.26C>T p.S9F (on ENST00000350501 / NM_198174.3; = p.S14F on NM_021180.3) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- GRIK3 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 70/332 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GRIN2C | c.2788C>T p.P930S | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2
- GRIP1 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 101/382 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- GUCY1B1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- H2AZ1 | c.290T>G p.L97W | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- HCN1 | c.648T>A p.N216K | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- HEPACAM2 | c.684G>A p.M228I (on ENST00000394468 / NM_001039372.4; = p.M216I on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- HEPHL1 | c.2708C>T p.P903L | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HERC2 | c.10456C>T p.P3486S | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HGSNAT | c.1342G>A p.G448R | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- HIVEP1 | c.793C>T p.H265Y | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- HIVEP3 | c.6958C>T p.Q2320* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | called by muse, mutect2, varscan2
- HMBS | c.344+5G>A | Splice Region (SNP) | VAF 89/401 reads (22%) | called by muse, mutect2, varscan2
- HMCN2 | c.13058C>T p.P4353L | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HMGXB3 | c.3254T>C p.V1085A (on ENST00000613459; = p.V839A on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- HNRNPH2 | c.260A>T p.K87M | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- HNRNPU | c.665G>A p.R222K (on ENST00000283179; = p.R284K on NM_004501.3) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- HS6ST2 | c.1651C>T p.P551S | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- HSD17B2 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- HTT | c.3632G>A p.R1211K | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- HYDIN | c.12481G>A p.G4161R | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- HYDIN | c.2243C>T p.S748F | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- IGDCC3 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- IGF2BP2 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.36); called by muse, mutect2
- IGFBP2 | c.118T>C p.F40L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHG3 | c.1157C>G p.A386G | Missense Mutation (SNP) | VAF 32/278 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.217); called by muse, varscan2
- IGSF9B | c.2450T>A p.L817Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- IL27 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- IMPG2 | c.1750C>T p.P584S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- INTS7 | c.2362C>T p.P788S | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- IRAK1 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.211); called by muse, mutect2
- ITGAD | c.2632A>C p.T878P | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ITGB3BP | c.74G>A p.R25K | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ITGB4 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 81/304 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- JOSD2 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 31/152 reads (20%) | called by muse, mutect2, varscan2
- JUNB | c.730C>G p.Q244E | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- KCNA3 | c.1060G>A p.G354R | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- KCNH6 | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 78/337 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- KCNH6 | c.2311G>A p.G771R | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNH8 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 54/174 reads (31%) | called by muse, mutect2, varscan2
- KCNJ10 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 41/189 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- KCNJ9 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KCNS1 | c.423G>A p.W141* | Nonsense Mutation (SNP) | VAF 47/192 reads (24%) | called by muse, mutect2, varscan2
- KCNS1 | c.422G>A p.W141* | Nonsense Mutation (SNP) | VAF 46/193 reads (24%) | called by muse, mutect2, varscan2
- KDM4E | c.1514C>T p.S505F | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- KDM4E | c.1516C>T p.L506F | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- KDM6B | c.826C>A p.L276I | Missense Mutation (SNP) | VAF 117/410 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- KIF26B | c.6091G>A p.V2031I | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KIF7 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
1,033 further variants in this file (328 protein-altering or splice-affecting, 505 silent, 200 other) are not listed here.
